Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2O, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2O-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

....

Clinical Diagnosis & History:
Left leg sarcoma.

Specimens Submitted:
1: SP: Radical resection of left leg sarcoma

DIAGNOSIS:

- 1) SOFT TISSUE, LEFT LEG, RADICAL RESECTION:
- HIGH GRADE MALIGNANT FIBROUS HISTIOCYTOMA, PLEOMORPHIC TYPE.
- TUMOR MEASURES 7.5 x 4.5 x 4.0 CM AND INVOLVES DERMIS AND SUBCUTANEOUS TISSUE.
- TUMOR COMES WITHIN 0.3 CM OF DEEP AND 0.5 CM OF SUPERIOR MARGIN.
- FOCAL NECROSIS (APPROXIMATELY 10%) IS NOTED.

NOTE: THE IMMUNOSTAINS SHOW THAT THE TUMOR IS FOCALLY POSITIVE FOR DESMIN AND NEGATIVE FOR MYOGENIN, SMA AND CD31. THIS IMMUNOPROFILE SUPPORTS THE ABOVE DIAGNOSIS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

Received fresh labeled as "Radical resection of left leg sarcoma, short suture superior, long suture lateral" is an elliptical segment of a skin with attached subcutaneous tissue weighing 198 grams. Orientation is provided by the surgeon (long suture-lateral, short suture-superior). The skin ellipse measures 14.0 (lateral to medial) x 9.0 (superior to inferior) x 0.2 (skin thickness) cm. Surface of the skin reveals bruise in the central aspect of the specimen (4.0 x 3.5 cm). Subcutaneous fibroadipose tissue measures 14.0 (lateral to medial) x 10.0 (superior to inferior) x 4.5 cm (superficial to deep). The specimen is inked as follows (lateral-yellow, medial-red, superior-green, inferior-blue, deep-black). Serial sections

** Continued on next page **

ICD-O-3
Histiocytoma, fibrous
malignant pleomorphic
8830/3
Site - Leg NOS C49.2
JW 3/10/14

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
reveal a fairly circumscribed tumor which measures 7.5 x 4.5 x 4.0 cm and is located 1.3 cm from the lateral margin, 1.0 cm from the inferior margin, 0.5 cm from the superior margin, and 4.0 cm from the medial margin. The tumor abuts the deep margin and skin. The cut surfaces of the tumor are predominantly fleshy with scattered areas of hemorrhage. A Cystic area containing blood and blood clots is noted in the deep/superior aspect of the tumor (approximately 2.5 x 2.0 x 2.0 cm). Photographs are taken. A portion of the tumor is submitted for TPS. Representative sections are submitted.

Summary of sections:

S Superior margin
I Inferior margin
M Medial margin
L Lateral margin
D Deep margin
SK Tumor with skin
RS Representative sections of the tumor

Summary of Sections:

Part 1: SP: Radical resection of left leg sarcoma

Block	Sect.	Site	PCs
2	D		0
2	I		0
1	L		0
1	M		0
10	RS		0
2	S		0
2	SK		0

** End of Report **

Source: NCI Genomic Data Commons file c0335c56-9b4a-44c8-94ad-8b011212e1b6 (TCGA-DX-AB2O.B94B890D-73FF-4E38-A1BC-DAC56C3FA2EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).